Somatic mutation profile of tumor specimen TCGA-EA-A439-01A (aliquot TCGA-EA-A439-01A-11D-A243-09) from TCGA case TCGA-EA-A439, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA1; Tumor grade: G3; Age at diagnosis: 50.7 years (18,529 days).
Specimen TCGA-EA-A439-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc65b54c-3470-475e-945d-810b55533478.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A439-10A (Blood Derived Normal), aliquot TCGA-EA-A439-10A-01D-A243-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/365e8856-cd92-41bc-aef5-475883895bca

The open-access MAF lists 121 somatic variants for this specimen: 80 protein-altering or splice-affecting, 38 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 38, Nonsense Mutation 6, Splice Site 2, Frame Shift Del 1, In Frame Del 1, RNA 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- CLCN4 | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777161, CM136397, COSV66466257, COSV66468819; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3736G>A p.D1246N (on ENST00000272895 / NM_173076.3; = p.D928N on NM_015657.3) | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55951652, COSV55977391; called by muse, mutect2, varscan2
- ALPL | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.411); catalogued as HM971627, COSV66380949; called by muse, mutect2, varscan2
- AP3B1 | c.1449G>A p.M483I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.262); catalogued as COSV54894093; called by muse, mutect2, varscan2
- ARHGAP32 | c.1168C>T p.Q390* (on ENST00000310343 / NM_001378025.1; = p.Q41* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV59856330; called by muse, mutect2, varscan2
- ATP1B1 | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369488918; called by muse, mutect2, varscan2
- C1GALT1C1 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV58974847; called by muse, mutect2, varscan2
- CALD1 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.107); catalogued as rs775880471, COSV62645445; called by mutect2, varscan2
- CD8A | c.182G>C p.R61P | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV52159715; called by muse, mutect2, varscan2
- CNOT3 | c.522G>C p.E174D | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV55368944; called by muse, mutect2, varscan2
- COL6A6 | c.1766G>C p.R589T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs545500523, COSV62038984; called by muse, mutect2, varscan2
- CRTC3 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV51597238; called by muse, mutect2, varscan2
- CUBN | c.2440C>G p.Q814E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV100912907, COSV64728294; called by muse, mutect2, varscan2
- CXCR4 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV54017374; called by muse, mutect2, varscan2
- DCAF8 | c.1736C>T p.S579F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58786130; called by muse, mutect2, varscan2
- DIDO1 | c.6127G>A p.E2043K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV56634818; called by muse, mutect2, varscan2
- DNAJC14 | c.1596G>A p.M532I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV54479416; called by muse, mutect2, varscan2
- DUOX2 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs376160362; called by muse, mutect2, varscan2
- EDA | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV100141045; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1959C>G p.F653L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100668326, COSV62571229; called by muse, mutect2
- EP400 | c.1454G>C p.R485P | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57787756; called by muse, mutect2, varscan2
- FAM120A | c.2506G>C p.E836Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV52911707; called by muse, mutect2, varscan2
- FAM47B | c.1517C>G p.S506* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV61453564, COSV61455745; called by muse, mutect2, varscan2
- FAM71B | c.1725G>C p.E575D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV57231543; called by muse, varscan2
- FLG | c.11443A>T p.N3815Y | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.346); catalogued as COSV64250650; called by muse, mutect2, varscan2
- FRMPD4 | c.2027A>T p.D676V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); catalogued as COSV66224212; called by muse, mutect2, varscan2
- FSTL5 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV60192279; called by muse, mutect2, varscan2
- GAL3ST1 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs150519649, COSV58891997; called by muse, mutect2, varscan2
- H3C11 | c.111G>C p.K37N | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV58900424; called by muse, mutect2, varscan2
- HECTD4 | c.10517C>G p.S3506C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV66400557; called by muse, mutect2, varscan2
- HFM1 | c.3881C>T p.S1294L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as COSV99647090; called by muse, mutect2, varscan2
- HYDIN | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs767319126, COSV55493204; called by muse, mutect2, varscan2
- IRX6 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV51861351; called by muse, mutect2, varscan2
- KIF1B | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs752393884, COSV55814599; called by muse, mutect2, varscan2
- KIF7 | c.1859C>T p.S620L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.334); catalogued as rs776869340, COSV67999637; called by muse, mutect2, varscan2
- LAMB3 | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as rs746335563, COSV61920106; called by muse, mutect2, varscan2
- LEP | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58241890; called by muse, mutect2, varscan2
- MEOX2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1421793823, COSV100012491, COSV56287804; called by muse, mutect2, varscan2
- MGAM | c.4404G>C p.Q1468H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as COSV72073927, COSV72075982; called by muse, mutect2, varscan2
- MIER1 | c.259G>A p.E87K (on ENST00000355356 / NM_001077701.3; = p.E104K on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.127); catalogued as COSV62532389; called by muse, mutect2, varscan2
- MRTFB | c.439C>G p.Q147E | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57962225; called by muse, mutect2, varscan2
- MUC6 | c.6752C>T p.T2251M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs199716176, COSV70150831; called by muse, mutect2, varscan2
- MUC6 | c.3968C>T p.S1323F | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV70150835; called by muse, mutect2, varscan2
- MYBPC2 | c.2047C>T p.Q683* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV63100320; called by muse, mutect2, varscan2
- NAV3 | c.4835G>A p.R1612Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs372156228; called by muse, mutect2, varscan2
- NELFE | c.606_629del p.E203_R210del | In Frame Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs1175117469; called by mutect2, pindel, varscan2
- NHS | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs764301455, COSV66283429; called by muse, mutect2, varscan2
- NLRC5 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV52660014; called by muse, mutect2, varscan2
- NRP2 | c.2492-1G>C p.X831_splice (on ENST00000360409 / NM_201266.2; = p.X826_splice on NM_003872.3) | Splice Site (SNP) | VAF 39/88 reads (44%) | catalogued as COSV63378607; called by muse, mutect2, varscan2
- NXPH1 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs769126264, COSV68320056; called by muse, varscan2
- PDK3 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs775948695, COSV64794588; called by muse, mutect2, varscan2
- PIBF1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58328771; called by muse, mutect2, varscan2
- POLK | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as rs747127083, COSV54040251; called by muse, mutect2, varscan2
- RAB2A | c.380G>A p.R127K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV52914407; called by muse, mutect2, varscan2
- RAE1 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758243618, COSV64799081; called by muse, mutect2, varscan2
- RPTOR | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV60819361; called by muse, mutect2, varscan2
- RTL9 | c.2795C>A p.A932D | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.469); catalogued as COSV71826496; called by muse, mutect2, varscan2
- SCCPDH | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63619413; called by muse, mutect2, varscan2
- SHLD1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV100290441, COSV57439817; called by muse, mutect2, varscan2
- SIRT2 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV50877636; called by muse, mutect2
- SLC16A2 | c.468C>G p.F156L | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV52089220; called by muse, mutect2, varscan2
- SLC16A2 | c.1511T>C p.M504T | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99331248; called by muse, mutect2, varscan2
- SLITRK6 | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV68391857; called by muse, mutect2, varscan2
- SMC3 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV62422622; called by muse, mutect2, varscan2
- SPPL3 | c.489G>A p.W163* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV62234608; called by muse, mutect2, varscan2
- SPTBN4 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58959880; called by muse, mutect2, varscan2
- TMEM234 | c.206T>G p.L69R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV59085833; called by muse, mutect2, varscan2
- TNRC18 | c.3513G>T p.E1171D | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs767140366, COSV68170928; called by muse, mutect2, varscan2
- TNXB | c.4700A>G p.D1567G (on ENST00000647633; = p.D1320G on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.499); catalogued as COSV64489663; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1581+1G>T p.X527_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | catalogued as COSV61459247; called by muse, mutect2, varscan2
- TTN | c.49329G>C p.L16443F (on ENST00000591111; = p.L9019F on NM_003319.4) | Missense Mutation (SNP) | VAF 27/99 reads (27%) | PolyPhen probably damaging (0.999); catalogued as COSV59933320; called by muse, mutect2, varscan2
- TTN | c.39889G>A p.V13297M (on ENST00000591111; = p.V5873M on NM_003319.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | PolyPhen possibly damaging (0.503); catalogued as rs367560855, COSV60206657; called by muse, mutect2
- TUBA8 | c.881C>G p.S294C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as rs970581729, COSV57814034; called by muse, mutect2
- USP9X | c.5704G>A p.D1902N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61075844; called by muse, mutect2, varscan2
- YPEL2 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as rs186477591; called by muse, mutect2, varscan2
- ZBTB2 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.144); catalogued as rs1366322491, COSV57314265; called by muse, mutect2, varscan2
- ZNF581 | c.329C>G p.S110W | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54402802; called by muse, mutect2, varscan2
- ZNF711 | c.2161C>T p.R721* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV52159394; called by mutect2, varscan2
- FAM71B | c.1801del p.E601Kfs*55 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by pindel, varscan2
- AGRN | c.4377G>T p.L1459= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV65072581; called by muse, mutect2, varscan2
- ATRX | c.471C>T p.L157= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100969480, COSV64870193; called by muse, mutect2, varscan2
- BAHCC1 | c.2274G>A p.T758= | Silent (SNP) | VAF 27/145 reads (19%) | catalogued as rs369219361; called by muse, mutect2, varscan2
- CACNG1 | c.285C>T p.F95= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs774956064, COSV56828012; called by muse, mutect2, varscan2
- CARD14 | c.2112C>T p.H704= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs751083330, COSV60127215; called by muse, mutect2, varscan2
- CELF2 | c.510G>C p.L170= (on ENST00000416382 / NM_001025077.3; = p.L177= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV59971694, COSV59983418; called by muse, mutect2, varscan2
- ECPAS | c.3870C>G p.L1290= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV52208672; called by muse, mutect2, varscan2
- FOXD4 | c.231C>T p.S77= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as rs763894392, COSV58703372; called by muse, mutect2
- GTF3C5 | c.1023G>A p.K341= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100565613; called by muse, mutect2, varscan2
- HYDIN | c.11175G>T p.R3725= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as rs1251057672, COSV101125267; called by muse, mutect2
- KCNK9 | c.873G>A p.P291= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as rs771770012, COSV57288975; called by muse, mutect2, varscan2
- KMT5C | c.1299C>T p.L433= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs764786236, COSV55320538; called by muse, mutect2, varscan2
- LRP1 | c.11292C>T p.F3764= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1435480741, COSV54507232; called by muse, mutect2, varscan2
- LRP1 | c.12813G>A p.V4271= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV54527678; called by muse, varscan2
- MYH1 | c.5352G>A p.E1784= | Silent (SNP) | VAF 53/172 reads (31%) | catalogued as rs754857698, COSV56858006; called by muse, mutect2, varscan2
- MYH14 | c.4719A>T p.T1573= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV51832856; called by mutect2, varscan2
- NFXL1 | c.2493G>A p.K831= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV67432977; called by muse, mutect2, varscan2
- NLGN1 | c.1680G>A p.T560= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs747826638, COSV64323475; called by muse, mutect2, varscan2
- NOC2L | c.528G>A p.A176= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs141993612; called by muse, mutect2, varscan2
- NRAP | c.1029C>T p.G343= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs1276610690, COSV63494288; called by muse, mutect2, varscan2
- OPCML | c.618C>T p.N206= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs143650226, COSV59403540; called by muse, mutect2, varscan2
- OR10H5 | c.378C>T p.I126= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV58279341; called by muse, mutect2, varscan2
- PCDHB11 | c.2034G>A p.P678= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as rs1554285710, COSV61310913; called by muse, mutect2, varscan2
- PDE6B | c.1584C>T p.G528= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs145273613; called by muse, mutect2, varscan2
- PLEC | c.7053G>A p.A2351= (on ENST00000322810 / NM_201380.4; = p.A2241= on NM_000445.5) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs559736151, COSV59700476; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PSMD11 | c.36C>T p.A12= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV55581551; called by muse, mutect2, varscan2
- RDM1 | c.396C>T p.I132= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs765443073; called by muse, mutect2, varscan2
- SERPINA6 | c.594C>G p.V198= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV58587879; called by muse, mutect2, varscan2
- SIGLEC10 | c.1740G>A p.Q580= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV59487049; called by muse, mutect2, varscan2
- SLC2A9 | c.670C>T p.L224= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV53329569; called by mutect2, varscan2
- SMG1 | c.7065C>T p.Y2355= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV67175067; called by muse, mutect2, varscan2
- SNAP29 | c.597C>T p.H199= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs1469096259, COSV53144370; called by muse, mutect2, varscan2
- SRRM4 | c.1677G>A p.R559= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV57428731; called by muse, mutect2
- TMEM132D | c.2010G>A p.V670= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV67162328; called by muse, mutect2, varscan2
- TMTC3 | c.273A>G p.S91= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV57123890; called by muse, mutect2, varscan2
- UBE2V2 | c.12C>T p.S4= | Silent (SNP) | VAF 80/113 reads (71%) | catalogued as rs1244861580, COSV101568656; called by muse, mutect2, varscan2
- ZFHX3 | c.366G>A p.E122= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV51738170; called by muse, mutect2, varscan2
- ZFYVE26 | c.6825C>T p.F2275= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV61334012; called by muse, mutect2
- BCAR1 | chr16:75267918 G>A | 5'Flank (SNP) | VAF 30/138 reads (22%) | catalogued as rs1055864597, COSV66504203; called by muse, mutect2, varscan2
- RPL26P30 | n.810G>A | RNA (SNP) | VAF 37/71 reads (52%) | catalogued as rs185039937; called by muse, mutect2, varscan2
- VWF | c.55+294G>A | Intron (SNP) | VAF 14/75 reads (19%) | catalogued as COSV54635923; called by muse, mutect2, varscan2
